Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3574, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3574-01A (Primary Tumor).

Diagnosis/ diagnoses:

Rectal resection preparation with an ulcerated rectal carcinoma histologically characterized as a moderately differentiated colorectal adenocarcinoma, extending at most to within 4 cm of the aboral resection margin, and with a maximum diameter of 6 cm at the widest point. Invasive tumor spread within all rectal wall layers up to the bordering periproctical soft tissue.

Oral and aboral resection margins are tumor-free.

18 periproctical and pericolic lymph nodes are tumor-free with non-characteristic reactive lesions.

Stage of tumor: pT3 pN0 (0/18) L0 V0; G2

Source: NCI Genomic Data Commons file 31cb5403-fdd6-4d20-ba59-31ea9dd5b3e8 (TCGA-AG-3574.DEEBB914-5BE7-4E94-A10C-185CB52AFDA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).